Somatic mutation profile of tumor specimen TCGA-VQ-A8PB-01A (aliquot TCGA-VQ-A8PB-01A-11D-A397-08) from TCGA case TCGA-VQ-A8PB, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-VQ-A8PB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a6a6372-b817-4294-81f2-5f28c448111c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PB-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PB-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/432e0351-4db1-4e91-82aa-41ec545ba9af

The open-access MAF lists 943 somatic variants for this specimen: 731 protein-altering or splice-affecting, 196 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 471, Silent 196, Frame Shift Del 176, Frame Shift Ins 40, Nonsense Mutation 22, Intron 9, Splice Region 8, In Frame Del 8, Splice Site 6, RNA 3, 3'UTR 2, 3'Flank 2.

Variants (750 of 943; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACADS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs199633532, CM067634, COSV54368245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB1 | c.1808G>A p.R603Q (on ENST00000360697 / NM_001346687.2; = p.R563Q on NM_001112.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364071684, COSV62346726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.4221del p.K1407Nfs*8 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs786204655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ALOX12B | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs397514532, CM081154, COSV59874078; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.1813dup p.I605Nfs*11 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs80359306; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CASQ2 | c.235-2A>G p.X79_splice | Splice Site (SNP) | VAF 23/73 reads (32%) | catalogued as rs1060502164, COSV99798231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2052del p.K684Nfs*38 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs121908746; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by mutect2, varscan2
- GPR179 | c.278del p.P93Qfs*57 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as rs794726685, CD121153; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.12019C>T p.Q4007* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs188017299, COSV56430202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MMUT | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as rs1238694184, CM060375, COSV51278193; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.491del p.K164Rfs*3 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs786204900, COSV64297274; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RP1 | c.3843del p.P1282Lfs*12 | Frame Shift Del (DEL) | VAF 38/222 reads (17%) | catalogued as rs769601671; ClinVar: pathogenic; called by mutect2, varscan2
- ZFYVE26 | c.4936C>T p.R1646* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as rs768366199, COSV100720706; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100748046, COSV100748073; called by muse, mutect2, varscan2
- ABCB6 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs553574357, COSV99522295; called by muse, varscan2
- ABCC4 | c.1342G>T p.G448* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100972821; called by muse, mutect2, varscan2
- ABRA | c.443A>T p.D148V | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100357663; called by muse, mutect2, varscan2
- AC018630.4 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs376002484; called by muse, mutect2, varscan2
- ACVR1B | c.671del p.G224Afs*10 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as COSV57777946; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 56/98 reads (57%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAM9 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101166278; called by muse, mutect2, varscan2
- ADAMTS7 | c.2908A>G p.T970A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV101183274; called by muse, mutect2, varscan2
- ADCY1 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99812949; called by muse, mutect2, varscan2
- ADCY3 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs150335965; called by muse, mutect2, varscan2
- ADCY5 | c.1462del p.Q488Rfs*5 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV59196700; called by mutect2, pindel, varscan2
- ADGRG2 | c.1387A>C p.T463P (on ENST00000379869 / NM_001079858.3; = p.T460P on NM_005756.4) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100492733; called by muse, mutect2
- ADGRG4 | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99796913; called by muse, mutect2, varscan2
- ADGRL3 | c.401G>A p.C134Y (on ENST00000506720 / NM_001322402.2; = p.C66Y on NM_015236.6) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547406; called by muse, mutect2, varscan2
- ADGRL3 | c.3166T>C p.Y1056H (on ENST00000506720 / NM_001322402.2; = p.Y988H on NM_015236.6) | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547407; called by muse, mutect2, varscan2
- ADGRV1 | c.4472C>T p.T1491M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs138373307, COSV67979898; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 42/182 reads (23%) | catalogued as rs748399150; called by mutect2, varscan2
- AHNAK2 | c.12307G>A p.V4103I | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.259); catalogued as rs1349179755, COSV100316914; called by muse, mutect2, varscan2
- AKT1 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV62574756; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALOX15B | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203473195, COSV101205720; called by muse, mutect2, varscan2
- ANAPC5 | c.1071C>A p.S357R | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.852); catalogued as COSV99946517; called by muse, mutect2
- ANGPT1 | c.1380G>T p.M460I | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99864358; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD28 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV101080958; called by muse, mutect2
- ANLN | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99732907; called by muse, mutect2
- APBB2 | c.1498G>A p.V500M (on ENST00000295974 / NM_001166050.2; = p.V501M on NM_004307.2) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs764979580, COSV55956397; called by muse, mutect2, varscan2
- APBB3 | c.1295G>A p.R432H (on ENST00000357560 / NM_133173.2; = p.R439H on NM_006051.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.7); catalogued as rs138766975; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGEF17 | c.5827G>A p.V1943I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.635); catalogued as rs377333672; called by muse, mutect2, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 34/175 reads (19%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARRB1 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100758202; called by muse, mutect2, varscan2
- ASH1L | c.7504A>G p.T2502A (on ENST00000368346 / NM_001366177.2; = p.T2497A on NM_018489.3) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100853611; called by muse, mutect2, varscan2
- ASIC5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753653000, COSV72232528; called by muse, mutect2, varscan2
- ASNSD1 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.351); catalogued as COSV53623167, COSV99641395; called by muse, mutect2, varscan2
- ASPRV1 | c.537del p.S180Afs*28 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs751747496; called by mutect2, pindel, varscan2
- ASXL2 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781134057, COSV55466033; called by muse, mutect2, varscan2
- ATP10B | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs374878756; called by muse, mutect2, varscan2
- ATP1B4 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs777736864; called by muse, mutect2
- ATP6V1D | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs767146743, COSV99370981; called by muse, mutect2, varscan2
- ATXN2 | c.3350G>A p.S1117N (on ENST00000550104; = p.S957N on NM_002973.4) | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); catalogued as rs1325259789, COSV101112744; called by muse, mutect2, varscan2
- AUH | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779230138, COSV100342837; called by muse, mutect2, varscan2
- BAG1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV101116740; called by muse, mutect2, varscan2
- BCL9L | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs555442453, COSV99420154; called by muse, mutect2, varscan2
- BCO2 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100730501; called by muse, mutect2
- BIRC6 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428974; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs747341586; called by mutect2, pindel, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BOD1L1 | c.7783T>A p.L2595M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV99240481; called by muse, mutect2, varscan2
- BRD7 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | catalogued as COSV67158826; called by muse, mutect2, varscan2
- BRD9 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as rs1390518375, COSV99386560; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.4021C>T p.R1341C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs142305207; called by muse, mutect2, varscan2
- BTAF1 | c.3456G>A p.W1152* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99795869; called by muse, mutect2, varscan2
- BTN2A2 | c.833T>C p.F278S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV100760599; called by muse, mutect2, varscan2
- BTNL9 | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100576279; called by muse, mutect2
- C12orf40 | c.628G>T p.V210F | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV100210801; called by muse, mutect2, varscan2
- C15orf39 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.267); catalogued as rs147159144; called by muse, varscan2
- C16orf89 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs999572208, COSV100280993; called by muse, mutect2, varscan2
- C1orf159 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.019); catalogued as COSV99618893; called by muse, mutect2
- C1orf194 | c.267_269del p.N89del (on ENST00000369948 / NM_001245025.3; = p.N77del on NM_001122961.2 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 29/137 reads (21%) | catalogued as rs1193163608; called by mutect2, pindel, varscan2
- C2orf69 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs767688764, COSV60666206, COSV60667094; called by muse, mutect2
- C3 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55573977; called by muse, varscan2
- CA11 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as rs767372249, COSV99320871; called by muse, varscan2
- CACFD1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as rs782678068, COSV52469040; called by muse, mutect2, varscan2
- CAD | c.6505C>G p.P2169A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99255804; called by muse, varscan2
- CAPN11 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369796036; called by muse, mutect2, varscan2
- CASKIN2 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs776777316, COSV100050809, COSV58593027; called by muse, mutect2, varscan2
- CASP8AP2 | c.5465A>G p.N1822S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs749146163, COSV99387585; called by muse, mutect2, varscan2
- CASQ1 | c.783A>T p.R261S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100927371; called by muse, mutect2, varscan2
- CATSPER3 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV99254336; called by muse, mutect2, varscan2
- CATSPER4 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs765377115, COSV100128531; called by muse, mutect2, varscan2
- CCDC110 | c.2248G>A p.V750I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as rs767005070, COSV56872076; called by muse, mutect2, varscan2
- CCL22 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1567549844, COSV99536667; called by muse, mutect2, varscan2
- CCT8 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs554540181, COSV99726176; called by muse, mutect2, varscan2
- CD69 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99946206; called by muse, mutect2, varscan2
- CEACAM5 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.342); catalogued as rs140053609, COSV99703704; called by muse, mutect2, varscan2
- CFAP61 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1260115348, COSV99846727; called by muse, mutect2, varscan2
- CHD4 | c.5007del p.K1670Rfs*3 (on ENST00000357008 / NM_001363606.2; = p.K1681Rfs*3 on NM_001273.5) | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as COSV100537881; called by mutect2, pindel, varscan2
- CHD7 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV101418474; called by muse, mutect2
- CHRM4 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.738); catalogued as COSV100642138; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 29/108 reads (27%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CHSY3 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100520019; called by muse, mutect2, varscan2
- CIC | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV99360330; called by muse, mutect2
- CILP | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99973970; called by muse, mutect2, varscan2
- CKM | c.1096_1098del p.K366del | In Frame Del (DEL) | VAF 64/200 reads (32%) | catalogued as rs780083622; called by pindel, varscan2
- CLASP1 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99757340; called by muse, mutect2, varscan2
- CLASP2 | c.2349C>T p.L783= | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as rs370915524; called by muse, mutect2, varscan2
- CLCN1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs563423438, COSV100578568, COSV58367949; called by muse, mutect2, varscan2
- CLEC4A | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV99983805; called by muse, mutect2
- CLUH | c.3155G>A p.R1052Q (on ENST00000435359; = p.R1091Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101425901; called by muse, mutect2, varscan2
- CMTM3 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV100726204; called by muse, mutect2, varscan2
- CNOT6 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99993855; called by muse, mutect2, varscan2
- CNTNAP1 | c.3422G>A p.G1141D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52851762, COSV99227056; called by muse, mutect2, varscan2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs1217756472; called by mutect2, pindel, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100618102; called by muse, mutect2, varscan2
- COL12A1 | c.6065C>T p.T2022M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59394041; called by muse, mutect2, varscan2
- COL22A1 | c.2781del p.G928Vfs*74 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs757423989, COSV100278932, COSV57328404; called by mutect2, varscan2
- COL6A1 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs150938324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS7A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs781411141, COSV99976467, COSV99976591; called by muse, mutect2
- CORO1A | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs763606361, COSV54631494; called by muse, mutect2
- CPT1C | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs967995964, COSV99773694; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 46/178 reads (26%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRACDL | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs951791497, COSV101194154; called by muse, mutect2, varscan2
- CREBZF | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV99476476; called by muse, mutect2, varscan2
- CSE1L | c.2866C>A p.L956I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs769741319, COSV99522290; called by muse, mutect2, varscan2
- CSMD3 | c.3847G>A p.A1283T (on ENST00000297405 / NM_001363185.1; = p.A1179T on NM_052900.3) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1367977593, COSV99848710; called by muse, mutect2
- CSNK2A1 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99424739; called by muse, mutect2, varscan2
- CSPG5 | c.1075T>C p.C359R | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99273613, COSV99274206; called by muse, mutect2, varscan2
- CTBP2 | c.316A>C p.S106R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100456945; called by muse, mutect2, varscan2
- CTNND1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1375089467, COSV100649820; called by muse, mutect2
- CYP2W1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs756819363, COSV100417335; called by muse, mutect2, varscan2
- DAGLA | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99944753; called by muse, mutect2, varscan2
- DAPK3 | c.269T>A p.V90D | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100009900; called by muse, mutect2, varscan2
- DAXX | c.1884dup p.C629Lfs*29 | Frame Shift Ins (INS) | VAF 43/162 reads (27%) | catalogued as rs1268651006; called by mutect2, pindel, varscan2
- DCAF12L1 | c.352A>G p.N118D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100948463; called by muse, mutect2, varscan2
- DCAF4L2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs138379350; called by muse, mutect2, varscan2
- DCC | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100498270, COSV59081935; called by muse, mutect2
- DDIT4L | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV56767079; called by muse, mutect2, varscan2
- DDX3X | c.298C>T p.R100W (on ENST00000399959; = p.R101W on NM_001356.5) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1175660869, COSV101302524; called by muse, mutect2, varscan2
- DENND2B | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as rs763802071, COSV58205734; called by muse, mutect2, varscan2
- DENND3 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751619785, COSV99371726; called by muse, mutect2, varscan2
- DENND5B | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1488658943, COSV60900651, COSV60902248; called by muse, mutect2
- DHX30 | c.2468C>T p.A823V (on ENST00000445061 / NM_138615.3; = p.A784V on NM_014966.3) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as COSV99276384; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs373108427; called by mutect2, varscan2
- DLEC1 | c.2245G>T p.G749C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100343546; called by muse, mutect2, varscan2
- DLL1 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100816197; called by muse, mutect2, varscan2
- DMAC2 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99700727; called by muse, mutect2, varscan2
- DMD | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767063127, COSV63754561; called by muse, mutect2, varscan2
- DMRTA2 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs1442105884, COSV101288911; called by muse, mutect2
- DNAH5 | c.10151C>A p.P3384H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99454518; called by muse, mutect2, varscan2
- DNHD1 | c.1397A>G p.H466R | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99601026; called by muse, mutect2, varscan2
- DNM1L | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs900218595, COSV56775771, COSV99846474; called by muse, mutect2, varscan2
- DNMT3A | c.1367del p.K456Sfs*195 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as rs1178623915; called by mutect2, pindel, varscan2
- DNTTIP1 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99708802; called by muse, mutect2, varscan2
- DOCK9 | c.4885G>A p.D1629N (on ENST00000376460 / NM_001366676.2; = p.D1630N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.555); catalogued as rs1209303879, COSV100241132; called by muse, mutect2, varscan2
- DOCK9 | c.1179T>C p.V393= (on ENST00000376460 / NM_001366676.2; = p.V394= on NM_015296.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100241135; called by muse, mutect2
- DOK2 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV52388654; called by muse, mutect2, varscan2
- DPY19L2 | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV60541558; called by muse, varscan2
- DR1 | c.521A>G p.D174G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV100937848; called by muse, mutect2, varscan2
- DST | c.6439C>A p.L2147I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV99760225; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs750962255; called by mutect2, varscan2
- DTNB | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV99978021, COSV99978072; called by muse, mutect2, varscan2
- DYSF | c.3352G>T p.G1118C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99250619; called by muse, mutect2, varscan2
- EBF2 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV68775934; called by muse, mutect2, varscan2
- ECM1 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100682316; called by muse, mutect2, varscan2
- EEF1A1 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100303453; called by muse, mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs773311790; called by mutect2, pindel, varscan2
- EGR1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53518935; called by muse, mutect2, varscan2
- EHF | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141066; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF3I | c.183C>T p.D61= | Splice Region (SNP) | VAF 15/46 reads (33%) | catalogued as rs780091515, COSV100557316; called by muse, mutect2, varscan2
- EIF4G2 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101151136; called by muse, mutect2, varscan2
- ELFN2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68744241; called by muse, varscan2
- ELP1 | c.3077G>A p.G1026D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV101010513; called by muse, mutect2, varscan2
- ENGASE | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100285976; called by muse, mutect2, varscan2
- ENTPD1 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751221623, COSV100967792; called by muse, mutect2, varscan2
- EPB41L1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753890218, COSV52443241, COSV99151768; called by muse, mutect2, varscan2
- EPHA10 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs777738447, COSV100361746; called by muse, mutect2, varscan2
- EPHA2 | c.2506C>T p.L836F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100626308; called by muse, mutect2, varscan2
- EPHA6 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.981); catalogued as COSV101065724; called by muse, mutect2, varscan2
- EPRS1 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770459831, COSV65098937; called by muse, mutect2, varscan2
- ESR2 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760053106, CM142389, COSV50831269, COSV99963815; called by muse, mutect2, varscan2
- EVX1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56085931, COSV56086022; called by muse, mutect2, varscan2
- F7 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs760341993, COSV100661110; called by muse, mutect2, varscan2
- FAHD2B | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374002655; called by muse, mutect2, varscan2
- FAM81A | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs1567078419, COSV99893629; called by muse, varscan2
- FAM9C | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100452898; called by muse, mutect2, varscan2
- FANCM | c.3362G>A p.S1121N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99951700; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT3 | c.3877T>A p.Y1293N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99971388; called by muse, mutect2, varscan2
- FAT3 | c.5395C>T p.R1799* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs868369232, COSV53153553, COSV99965750; called by muse, mutect2, varscan2
- FAT4 | c.6292A>G p.S2098G | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1181581377, COSV100630300; called by muse, mutect2, varscan2
- FBF1 | c.3130C>T p.R1044* (on ENST00000586717; = p.R1059* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs1414757080, COSV100045619; called by muse, mutect2, varscan2
- FBXL12 | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99928142; called by muse, mutect2, varscan2
- FBXO42 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100981945; called by muse, mutect2, varscan2
- FBXO43 | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101413924; called by muse, mutect2, varscan2
- FCRLB | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs548692484, COSV100396391; called by muse, mutect2, varscan2
- FDFT1 | c.977T>C p.M326T | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.934); catalogued as COSV99594907; called by muse, mutect2, varscan2
- FEM1A | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as rs1182530964, COSV99521572; called by muse, mutect2, varscan2
- FFAR3 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV100588313; called by mutect2, varscan2
- FGFR3 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.209); catalogued as rs1200851427, COSV99603547; called by mutect2, varscan2
- FGFRL1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs745887685, COSV99294868; called by muse, mutect2, varscan2
- FGFRL1 | c.1454A>T p.H485L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as rs1434034079, COSV53258165; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as rs755527396; called by mutect2, varscan2
- FKBP11 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs763659306, COSV99872891; called by muse, mutect2, varscan2
- FLAD1 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99423078; called by muse, mutect2, varscan2
- FLNB | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762205881, COSV55883400; called by muse, mutect2, varscan2
- FLNB | c.6973A>G p.S2325G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.631); catalogued as COSV99915039; called by muse, mutect2, varscan2
- FMNL1 | c.1082G>T p.R361M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1005428446, COSV100056976; called by muse, mutect2, varscan2
- FOCAD | c.2579G>A p.S860N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV58099021; called by muse, mutect2, varscan2
- FOXO4 | c.1203dup p.L402Afs*6 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | catalogued as rs754124740; called by mutect2, varscan2
- FRAS1 | c.1887dup p.K630Qfs*19 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs776570778; called by mutect2, varscan2
- FRY | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as rs776423516, COSV100969956; called by muse, mutect2, varscan2
- FSCN1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV61018454, COSV61018701; called by muse, mutect2, varscan2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 23/79 reads (29%) | catalogued as rs751048223; called by mutect2, varscan2
- GAL3ST3 | c.558_559del p.P187Rfs*27 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs1490154966; called by pindel, varscan2
- GALNT10 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99769941; called by muse, mutect2, varscan2
- GARRE1 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs774755279, COSV55099658; called by muse, mutect2, varscan2
- GBF1 | c.5212G>A p.A1738T (on ENST00000369983 / NM_001377137.1; = p.A1737T on NM_004193.3) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.576); catalogued as rs1047535189, COSV64145359; called by muse, mutect2, varscan2
- GCG | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100972860; called by muse, mutect2, varscan2
- GINS3 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV100139408; called by muse, mutect2
- GJA4 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs758492393, COSV100654776; called by muse, mutect2, varscan2
- GJA9 | c.717_718del p.G241Afs*12 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | catalogued as rs765664608; called by mutect2, pindel, varscan2
- GNA12 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as rs771969963, COSV99283099; called by muse, mutect2, varscan2
- GNPTG | c.241T>C p.Y81H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99201666; called by muse, mutect2, varscan2
- GOLPH3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs779400964, COSV99417515; called by muse, mutect2, varscan2
- GON4L | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs771889711, COSV55196515; called by muse, mutect2, varscan2
- GRIA2 | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.09); catalogued as COSV99643610, COSV99645191; called by muse, mutect2
- GRIN2B | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs766060662, COSV101663026; called by muse, mutect2, varscan2
- GRM6 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs751541548, COSV51444853; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs754199513; called by mutect2, varscan2
- GSE1 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV99497254; called by muse, mutect2, varscan2
- GSN | c.2118G>T p.Q706H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376571; called by muse, mutect2, varscan2
- H2BC8 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.132); catalogued as COSV99773409; called by muse, mutect2, varscan2
- HAPLN2 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815535; called by muse, mutect2, varscan2
- HDAC7 | c.356C>T p.P119L (on ENST00000427332; = p.P158L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV99316966; called by muse, mutect2, varscan2
- HDGFL1 | c.210C>A p.N70K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs563167910, COSV100014733; called by muse, mutect2, varscan2
- HECTD3 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771331452, COSV55801332; called by muse, mutect2, varscan2
- HECTD4 | c.11687G>A p.R3896H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs781440455, COSV66387913; called by muse, mutect2, varscan2
- HFM1 | c.4163del p.N1388Tfs*37 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | catalogued as rs759278255; called by mutect2, pindel, varscan2
- HLA-G | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100827204; called by muse, mutect2, varscan2
- HOXD1 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 6/141 reads (4%) | catalogued as COSV100514127, COSV100514270; called by muse, mutect2
- HOXD8 | c.329dup p.P111Sfs*31 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs770632206; called by mutect2, varscan2
- HS3ST1 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99137021; called by muse, mutect2, varscan2
- HSPA1L | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV100989455, COSV100989461; called by muse, mutect2, varscan2
- HTR1B | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.725); catalogued as COSV100885499, COSV64051427; called by muse, mutect2, varscan2
- HTR3E | c.610G>A p.A204T (on ENST00000415389 / NM_001256613.1; = p.A219T on NM_182589.2) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371514444, COSV58945737; called by muse, mutect2, varscan2
- HTT | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs745573312, COSV100751280; called by muse, mutect2, varscan2
- HUWE1 | c.11357G>A p.R3786Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs1397073912, COSV53359324; called by muse, mutect2, varscan2
- ICE1 | c.6068C>T p.P2023L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99665799; called by muse, mutect2
- ICE2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs201440459, COSV99831861; called by muse, mutect2, varscan2
- IFNA16 | c.116T>G p.I39R | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV101207088; called by muse, mutect2, varscan2
- IGLV7-46 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs536317077; called by muse, mutect2
- IHH | c.397T>C p.W133R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838804; called by muse, mutect2, varscan2
- IKBKE | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs782242787, COSV65625638; called by muse, mutect2, varscan2
- ILKAP | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1010751554, COSV99611188; called by muse, mutect2, varscan2
- IMPDH1 | c.1382C>T p.A461V (on ENST00000470772 / NM_001142573.2; = p.A547V on NM_000883.4) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs1329171105, COSV100118823; called by muse, mutect2, varscan2
- INPP5A | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs139296617; called by muse, mutect2, varscan2
- IRS1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100524992, COSV59333333; called by muse, mutect2, varscan2
- ITPR3 | c.3857T>G p.F1286C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968158; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1232G>A p.R411H (on ENST00000439118 / NM_001008949.3; = p.R419H on NM_178495.6) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs768421706, COSV100742249; called by muse, mutect2, varscan2
- JAG2 | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs746879958, COSV59305998; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNG2 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV100302125; called by muse, mutect2, varscan2
- KCNJ10 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as COSV100927962; called by muse, mutect2, varscan2
- KCNK4 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs760591980, COSV100107851; called by muse, mutect2, varscan2
- KCNQ5 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as rs763365816, COSV100573232; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KIAA0232 | c.3585G>T p.Q1195H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs778330055, COSV100301123; called by muse, mutect2, varscan2
- KIAA1210 | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68178127; called by muse, mutect2, varscan2
- KIAA1217 | c.213dup p.P72Afs*14 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | catalogued as rs755705172; called by mutect2, pindel, varscan2
- KIAA1522 | c.1543C>A p.P515T (on ENST00000373480 / NM_001198972.2; = p.P574T on NM_020888.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.872); catalogued as COSV53863859, COSV53865839; called by muse, mutect2, varscan2
- KIAA1841 | c.89T>A p.I30N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99694240; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF21A | c.3703del p.I1235Ffs*7 (on ENST00000361418 / NM_001378440.1; = p.I1222Ffs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs761074592; called by mutect2, varscan2
- KMT2A | c.10067C>T p.A3356V | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs149340870, COSV63283642; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KRT25 | c.899C>G p.T300S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV100380105; called by muse, mutect2, varscan2
- KRT25 | c.732del p.V246Wfs*7 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as COSV100379923; called by mutect2, pindel, varscan2
- KRT34 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as rs779910638, COSV101222727; called by muse, mutect2, varscan2
- KRT6B | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs1701772, COSV99361039; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | catalogued as COSV60222740; called by mutect2, varscan2
- LBR | c.1270A>G p.N424D | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99687751; called by muse, mutect2, varscan2
- LCMT2 | c.427del p.E143Sfs*49 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs1277104000; called by mutect2, pindel, varscan2
- LETM1 | c.432del p.A145Qfs*5 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs745839823; called by mutect2, pindel, varscan2
- LHFPL3 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101308968, COSV67810885; called by muse, mutect2, varscan2
- LILRA5 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100007119; called by muse, mutect2, varscan2
- LIMCH1 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100574525; called by muse, mutect2, varscan2
- LIX1L | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100995865; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMAN1L | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1366395705, COSV100547722, COSV59003215; called by muse, mutect2, varscan2
- LMTK2 | c.2707C>T p.L903F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99807844; called by muse, mutect2, varscan2
- LRBA | c.6352dup p.I2118Nfs*61 | Frame Shift Ins (INS) | VAF 48/238 reads (20%) | catalogued as COSV58264100; called by mutect2, varscan2
- LRIG2 | c.225del p.D76Tfs*27 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs768751013; called by mutect2, pindel, varscan2
- LRIT1 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369831951; called by muse, mutect2, varscan2
- LRP10 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs201213246, COSV62078133; called by muse, mutect2, varscan2
- LRP1B | c.13610C>T p.A4537V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.939); catalogued as rs376526778, COSV67255727; called by muse, mutect2, varscan2
- LRP2 | c.13270G>A p.A4424T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs774009040, COSV55555431; called by muse, mutect2, varscan2
- LRP5 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1462356607, COSV99591566; called by muse, mutect2, varscan2
- LRP6 | c.3383G>A p.S1128N | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as rs755158176, COSV99744564; called by muse, mutect2, varscan2
- LRRC32 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs367700341; called by muse, mutect2, varscan2
- LRRFIP1 | c.1651G>A p.D551N (on ENST00000392000 / NM_001137552.2; = p.D527N on NM_004735.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs182108447; called by muse, mutect2, varscan2
- MAP3K21 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100786316, COSV64046319; called by muse, mutect2, varscan2
- MAPK10 | c.65T>A p.V22D (on ENST00000359221 / NM_001351625.2; = p.V60D on NM_002753.5) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100175491; called by muse, mutect2, varscan2
- MAPKBP1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs200270151, COSV99530204; called by muse, mutect2, varscan2
- MARK2 | c.1544C>T p.T515M (on ENST00000402010 / NM_001039469.2; = p.T481M on NM_017490.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as rs779235042, COSV100159183; called by muse, mutect2, varscan2
- MATN4 | c.1008T>G p.C336W (on ENST00000372754; = p.C295W on NM_003833.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV100637177; called by muse, mutect2, varscan2
- MBD3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV99337087; called by muse, mutect2, varscan2
- MCC | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as rs765539734, COSV56738733; called by muse, mutect2, varscan2
- MDGA1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs370697927; called by muse, mutect2, varscan2
- MED23 | c.2427-1G>A p.X809_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100645411; called by muse, mutect2, varscan2
- MED25 | c.801del p.V268Sfs*11 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV57204197; called by mutect2, pindel
- MEX3B | c.828del p.G277Afs*49 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as COSV61663174; called by mutect2, pindel, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as rs780635289; called by mutect2, varscan2
- MGA | c.4180C>T p.R1394C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367727094; called by muse, mutect2, varscan2
- MIDN | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1438859755, COSV99960247; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINDY1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201811445, COSV56497908; called by muse, mutect2, varscan2
- MMACHC | c.547_548del p.V183Tfs*5 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs1305170860; called by pindel, varscan2
- MMP20 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs555548044, COSV99498012; called by muse, mutect2, varscan2
- MNT | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV99438350; called by muse, mutect2, varscan2
- MPP2 | c.245C>T p.T82M (on ENST00000461854 / NM_001278372.2; = p.T58M on NM_005374.5) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as rs755175397, COSV52235417; called by muse, mutect2, varscan2
- MROH1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745906494, COSV100396124; called by muse, mutect2, varscan2
- MTRF1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs376093788, COSV101067514; called by muse, mutect2, varscan2
- MUC4 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.685); catalogued as rs781336737, COSV62154434; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs764857791; called by mutect2, varscan2
- MYF5 | c.502-1G>A p.X168_splice | Splice Site (SNP) | VAF 22/95 reads (23%) | catalogued as COSV57354720; called by muse, mutect2, varscan2
- MYLK | c.4895T>C p.V1632A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100659682; called by muse, mutect2, varscan2
- MYO18B | c.6494C>T p.T2165I | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100125296; called by muse, mutect2, varscan2
- MYO5C | c.4696G>A p.G1566S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1237965656, COSV55903176; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAA10 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV100604186; called by muse, mutect2, varscan2
- NAV3 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57060987; called by muse, mutect2, varscan2
- NBEA | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267603808, COSV59766496, COSV59830102; called by muse, mutect2, varscan2
- NBEAL1 | c.7307A>G p.H2436R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV68916699; called by muse, mutect2, varscan2
- NBEAL2 | c.3898G>A p.G1300S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs575957245, COSV99437706; called by muse, mutect2, varscan2
- NBEAL2 | c.4841G>A p.R1614H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs186059483, COSV99437710; called by muse, mutect2, varscan2
- NBR1 | c.2852C>T p.T951I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833012; called by muse, mutect2, varscan2
- NCKIPSD | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as rs1194013392, COSV99584282; called by muse, mutect2, varscan2
- NDUFA4 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1286100412, COSV60011788; called by muse, varscan2
- NEO1 | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982838; called by muse, mutect2, varscan2
- NEURL1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as rs575166034, COSV63915793; called by muse, mutect2, varscan2
- NFASC | c.230G>A p.R77Q (on ENST00000339876 / NM_001378329.1; = p.R71Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757003214, COSV58365309; called by muse, mutect2, varscan2
- NFATC2 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs749298884, COSV101044752; called by muse, mutect2, varscan2
- NFE2 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.225); catalogued as rs779929770, COSV100380859; called by muse, mutect2, varscan2
- NHS | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs767956070, COSV66272541, COSV66282606; called by muse, mutect2, varscan2
- NIBAN2 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541599134, COSV64824507; called by muse, mutect2, varscan2
- NLRC5 | c.1346dup p.G450Wfs*105 | Frame Shift Ins (INS) | VAF 11/64 reads (17%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NLRP7 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs1339008404, COSV100053507, COSV60176547; called by muse, mutect2, varscan2
- NLRX1 | c.1887del p.L630Ffs*10 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | catalogued as rs749769992; called by mutect2, pindel, varscan2
- NMBR | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141190379; called by muse, mutect2, varscan2
- NMBR | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99237546; called by muse, mutect2, varscan2
- NOC4L | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs749375574, COSV57957663; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, varscan2
- NPAS3 | c.2107G>A p.G703S (on ENST00000356141 / NM_001164749.2; = p.G671S on NM_022123.3) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as COSV100640722; called by muse, mutect2, varscan2
- NPEPL1 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV100622597; called by muse, mutect2, varscan2
- NPNT | c.253del p.T85Pfs*6 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs779447711, COSV59751584; called by pindel, varscan2
- NPNT | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs1029664996, COSV99975493; called by muse, mutect2, varscan2
- NR2F6 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as rs773419411, COSV52244728; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN2 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs770105914, COSV99634989; called by muse, mutect2, varscan2
- NRXN2 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1309339564, COSV55456906; called by muse, mutect2, varscan2
- NUBP2 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752791500, COSV99236705; called by muse, mutect2, varscan2
- NUBPL | c.191_193del p.E64del | In Frame Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs1555310880; called by mutect2, varscan2
- NUBPL | c.707T>A p.V236D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99810374; called by muse, mutect2, varscan2
- NUP188 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs370614354; called by muse, mutect2, varscan2
- NUP43 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs769355579, COSV61191334; called by muse, mutect2, varscan2
- NXPE4 | c.1285A>G p.T429A (on ENST00000375478 / NM_001077639.2; = p.T145A on NM_017678.3) | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100970567; called by muse, mutect2, varscan2
- OBSCN | c.6839G>A p.R2280Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs562143677, CM142523, COSV52769481, COSV99484604; called by muse, mutect2, varscan2
- OLFML2A | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99992909; called by muse, mutect2, varscan2
- OLIG3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs771490973, COSV100880344; called by muse, varscan2
- OR10H4 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 75/358 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761520896, COSV100437791; called by muse, mutect2, varscan2
- OR13F1 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200699312, COSV100594862; called by muse, mutect2, varscan2
- OR1A1 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100410839; called by muse, mutect2, varscan2
- OR5AU1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs754311632, COSV100436224; called by muse, mutect2, varscan2
- OR9G4 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100265273; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as CD124838, COSV100258088; called by mutect2, varscan2
- P2RX3 | c.710del p.X237_splice | Splice Site (DEL) | VAF 8/27 reads (30%) | catalogued as rs756989873; called by pindel, varscan2
- PABPC3 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs371964552, COSV55802561; called by muse, mutect2, varscan2
- PABPC5 | c.277T>C p.W93R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100442698; called by muse, varscan2
- PALB2 | c.2641G>A p.G881S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs766315705, COSV99849015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPPA | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100075425; called by muse, mutect2, varscan2
- PARD3 | c.2273C>T p.T758I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100402070; called by muse, mutect2, varscan2
- PARPBP | c.944del p.N315Ifs*10 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as COSV59676272; called by mutect2, pindel, varscan2
- PASK | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs778811482, COSV99300293; called by muse, mutect2, varscan2
- PATJ | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); catalogued as rs545651035, COSV57155825; called by muse, mutect2, varscan2
- PAX1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs780254769, COSV68271710; called by muse, mutect2, varscan2
- PCDH12 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs374457419; called by muse, mutect2, varscan2
- PCDH8 | c.1670C>A p.A557D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100132070; called by muse, mutect2, varscan2
- PCDHAC2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53848370; called by muse, mutect2
- PCDHB7 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs370716235, COSV99177027; called by muse, mutect2, varscan2
- PCDHGA3 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as rs746729408, COSV53965809; called by muse, mutect2, varscan2
- PCDHGB1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs761825346, COSV53897810; called by muse, mutect2, varscan2
- PCLO | c.13316G>A p.R4439H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs371995456; called by muse, mutect2, varscan2
- PCLO | c.4204A>G p.S1402G | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV100438212; called by muse, mutect2, varscan2
- PCNX4 | c.1987C>T p.R663C (on ENST00000406854 / NM_001330177.2; = p.R429C on NM_022495.5) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747512999, COSV58302068; called by muse, varscan2
- PFAS | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs199863834, COSV100119177; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKB | c.1929del p.G644Efs*2 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs35494330; called by mutect2, pindel, varscan2
- PI4KB | c.1132G>A p.V378M (on ENST00000368873 / NM_001369623.1; = p.V390M on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs764847655, COSV99649727; called by muse, mutect2, varscan2
- PIK3C2B | c.4886G>A p.R1629Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs770075841, COSV65809217; called by muse, mutect2, varscan2
- PIK3C2G | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as rs752140066, COSV99854125; called by muse, mutect2, varscan2
- PIK3C3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56277681, COSV56284442; called by muse, mutect2, varscan2
- PINK1 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as rs773843241, CM1212782, COSV58632262; called by muse, mutect2, varscan2
- PIP4K2A | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV100114698; called by muse, mutect2, varscan2
- PIWIL4 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as rs760210104, COSV100133343; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | catalogued as rs745860467; called by mutect2, varscan2
- PLAG1 | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.112); catalogued as rs1418890719, COSV100388286; called by muse, mutect2, varscan2
- PLD2 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99562725; called by muse, mutect2, varscan2
- PLEC | c.9247C>T p.R3083C (on ENST00000322810 / NM_201380.4; = p.R2973C on NM_000445.5) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs546852080, COSV59660821; called by muse, mutect2, varscan2
- PLEC | c.1312G>A p.A438T (on ENST00000322810 / NM_201380.4; = p.A328T on NM_000445.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs573432728; called by muse, mutect2
- PLEKHH2 | c.4039C>T p.P1347S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs1235800734, COSV99175125; called by muse, mutect2, varscan2
- PLEKHM1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs148973891; called by muse, mutect2, varscan2
- PLIN3 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99701734; called by muse, mutect2, varscan2
- PLK1 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100267499; called by muse, mutect2, varscan2
- PLK2 | c.1202A>T p.D401V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV99956304; called by muse, mutect2, varscan2
- PML | c.1147C>A p.L383M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99167940; called by muse, mutect2, varscan2
- PMS1 | c.1324A>C p.S442R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100575777; called by muse, mutect2, varscan2
- PNLIPRP1 | c.813G>A p.A271= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as rs201391346, COSV100724535; called by muse, mutect2
- PPIP5K2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV100384262; called by muse, mutect2, varscan2
- PPP1R26 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs1213288648, COSV100778163; called by muse, mutect2, varscan2
- PPP1R9A | c.2391del p.A798Lfs*24 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as COSV56902855; called by mutect2, pindel, varscan2
- PPT2 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs945364426, COSV99278676; called by muse, mutect2, varscan2
- PREX2 | c.3462A>T p.K1154N | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99910151; called by muse, mutect2, varscan2
- PRG4 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100798333; called by muse, mutect2, varscan2
- PRICKLE4 | c.953G>A p.R318H (on ENST00000359201; = p.R358H on NM_013397.6) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV100138917; called by muse, mutect2, varscan2
- PRKD2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs774048512, COSV52184657; called by muse, mutect2, varscan2
- PROM2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs537196418, COSV100469102, COSV100469421; called by muse, mutect2, varscan2
- PROX1 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV99800265; called by muse, mutect2, varscan2
- PRPSAP1 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100221780; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1798C>T p.H600Y (on ENST00000352766; = p.H521Y on NM_181334.5) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100424699; called by muse, mutect2, varscan2
- PSMD1 | c.372dup p.P125Tfs*3 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs1559217151; called by mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 40/120 reads (33%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTH2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs1351040747, COSV99569633; called by muse, mutect2, varscan2
- PTK7 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100030676; called by muse, mutect2, varscan2
- PTPN22 | c.2253T>C p.S751= (on ENST00000359785 / NM_001193431.2; = p.S696= on NM_012411.5) | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100703983; called by mutect2, varscan2
- PTPRG | c.2908A>T p.S970C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99877013; called by muse, mutect2, varscan2
- PTPRS | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs148739536, COSV53641507; called by muse, mutect2, varscan2
- RAB26 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99270020; called by muse, mutect2, varscan2
- RAD54L | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142375065; called by muse, mutect2, varscan2
- RAD54L2 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771939905, COSV99621290; called by muse, mutect2, varscan2
- RALY | c.409G>A p.V137M (on ENST00000246194 / NM_016732.3; = p.V121M on NM_007367.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs762486256, COSV99866226; called by muse, varscan2
- RANBP17 | c.1884dup p.L629Tfs*17 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs779856373; called by mutect2, varscan2
- RANBP3 | c.1190C>T p.A397V (on ENST00000340578 / NM_007322.3; = p.A392V on NM_003624.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs766503194, COSV99222517; called by muse, mutect2, varscan2
- RBM27 | c.2675T>C p.V892A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99506666; called by muse, mutect2, varscan2
- RECK | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1181099635, COSV65034643; called by muse, mutect2, varscan2
- RECQL5 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100512371; called by muse, mutect2
- RELN | c.6646C>T p.R2216* | Nonsense Mutation (SNP) | VAF 31/160 reads (19%) | catalogued as rs1368573599, COSV100633984, COSV59033733; called by muse, mutect2, varscan2
- RGL1 | c.433G>A p.A145T (on ENST00000360851 / NM_001297672.2; = p.A180T on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.624); catalogued as rs1388410955, COSV58996980; called by muse, mutect2, varscan2
- RGS11 | c.686A>G p.E229G (on ENST00000397770 / NM_183337.3; = p.E208G on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99396049; called by muse, mutect2, varscan2
- RIT2 | c.480dup p.E161* | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | catalogued as rs754174204; called by mutect2, varscan2
- RLF | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.384); catalogued as COSV101035716; called by muse, mutect2, varscan2
- RNF14 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100641309, COSV61662676; called by muse, mutect2, varscan2
- RNF144A | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.467); catalogued as COSV100306150; called by muse, mutect2, varscan2
- RNF31 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs748079228, COSV99396301; called by muse, mutect2, varscan2
- RNGTT | c.1248del p.F416Lfs*18 | Frame Shift Del (DEL) | VAF 35/123 reads (28%) | catalogued as rs1241639328; called by mutect2, pindel, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL7A | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV100034865; called by muse, mutect2, varscan2
- RPSA | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV100088276; called by muse, mutect2, varscan2
- RTKN | c.713del p.G238Vfs*70 (on ENST00000272430 / NM_001015055.2; = p.G225Vfs*70 on NM_033046.2) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs756896464; called by mutect2, pindel, varscan2
- SAMD14 | c.855del p.S286Afs*67 (on ENST00000330175 / NM_001257359.2; = p.S314Afs*67 on NM_174920.4) | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs1567718169; called by mutect2, pindel, varscan2
- SAP130 | c.1458A>T p.Q486H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); catalogued as rs752896726, COSV52095583, COSV52099289; called by muse, mutect2, varscan2
- SBF1 | c.4679T>C p.L1560P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); catalogued as COSV100818050; called by muse, mutect2, varscan2
- SDF4 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs778380110, COSV55417693; called by muse, mutect2, varscan2
- SDK1 | c.2647T>C p.S883P | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101269890; called by muse, mutect2, varscan2
- SDK2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1192577031, COSV66185744; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC61A1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99685049; called by muse, mutect2, varscan2
- SELE | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs752904063, COSV100325175; called by muse, mutect2, varscan2
- SELENOO | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.416); catalogued as rs201408834, COSV66600994; called by muse, mutect2, varscan2
- SERPINA11 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1282929332, COSV58241754, COSV58242427; called by muse, mutect2, varscan2
- SEZ6 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs573525885, COSV57976881; called by muse, mutect2, varscan2
- SFRP5 | c.682_684del p.K228del | In Frame Del (DEL) | VAF 22/109 reads (20%) | catalogued as rs757855988; called by pindel, varscan2
- SGCZ | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66020478; called by muse, mutect2, varscan2
- SGPL1 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as rs749229998, COSV100940467; called by muse, mutect2, varscan2
- SKOR1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58244651; called by muse, mutect2, varscan2
- SLC18A1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs750496793, COSV52346629; called by muse, mutect2, varscan2
- SLC25A12 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs780217724, COSV99785454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs782676413, COSV53403488; called by muse, mutect2, varscan2
- SLC27A5 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs149015959; ClinVar: uncertain significance; called by muse, varscan2
- SLC28A3 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as rs746125522, COSV66152711; called by muse, mutect2, varscan2
- SLC35A2 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); catalogued as COSV54430668, COSV99504584; called by muse, mutect2, varscan2
- SLC38A4 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99873172; called by muse, mutect2, varscan2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | catalogued as rs771462597; called by mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A4 | c.612C>A p.G204= (on ENST00000517878 / NM_001286646.2; = p.G153= on NM_001080431.2) | Splice Region (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99200571; called by muse, mutect2, varscan2
- SLC5A6 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs546600819, COSV60159005; called by muse, mutect2, varscan2
- SLC5A6 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143614; called by muse, mutect2, varscan2
- SLC6A2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776659407, COSV54923884; called by muse, mutect2, varscan2
- SLC9C2 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100877020, COSV62943761; called by muse, mutect2, varscan2
- SLCO6A1 | c.1068del p.F356Lfs*8 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs777416753; called by mutect2, varscan2
- SLIT2 | c.68T>A p.V23E | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV99887547; called by muse, mutect2, varscan2
- SLITRK2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100157323, COSV100158253; called by muse, mutect2, varscan2
- SLITRK5 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100281241; called by muse, mutect2, varscan2
- SLX4 | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99568622; called by muse, mutect2, varscan2
- SMARCAD1 | c.2515C>T p.H839Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.242); catalogued as COSV100759041; called by muse, mutect2, varscan2
- SMG6 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.153); catalogued as rs376009586; called by muse, mutect2, varscan2
- SMO | c.1916T>C p.V639A | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99977136; called by muse, mutect2, varscan2
- SMOX | c.908del p.G303Afs*20 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs746816975, COSV53864789; called by mutect2, pindel, varscan2
- SMPD4 | c.1954C>T p.R652W (on ENST00000409031 / NM_017951.4; = p.R623W on NM_017751.4) | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs751109777, COSV100302802; called by muse, mutect2
- SMYD1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101352403, COSV70226000, COSV70226034; called by muse, mutect2, varscan2
- SOWAHC | c.1498del p.E500Rfs*18 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs752137412; called by mutect2, pindel, varscan2
- SOX7 | c.463dup p.A155Gfs*10 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs769092194; called by mutect2, pindel, varscan2
- SPATA16 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV100651706; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEG | c.6871G>A p.E2291K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56667893; called by muse, mutect2, varscan2
- SPINK5 | c.2666+2T>C p.X889_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99807395; called by muse, mutect2, varscan2
- SPIRE2 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771098673, COSV100989022; called by muse, mutect2, varscan2
- SPRY3 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 35/132 reads (27%) | catalogued as COSV100249588; called by muse, mutect2, varscan2
- SPTBN1 | c.5261G>A p.R1754H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100443463; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs748467821; called by mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as rs753297385; called by mutect2, varscan2
- STOML3 | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV65510253, COSV65511214; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2256G>T p.L752F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100562309; called by muse, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYNE1 | c.10229C>T p.A3410V (on ENST00000367255 / NM_182961.4; = p.A3417V on NM_033071.3) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99580017; called by muse, mutect2, varscan2
- SYNE2 | c.5488del p.S1830Vfs*11 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs1433291261; called by mutect2, pindel, varscan2
- SYNE2 | c.20150A>G p.Q6717R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100648529; called by muse, mutect2, varscan2
- SZT2 | c.10154C>T p.T3385M (on ENST00000634258 / NM_001365999.1; = p.T3328M on NM_015284.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs563977596, COSV65094609; called by muse, mutect2, varscan2
- TACC2 | c.5728C>G p.L1910V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV100554065; called by muse, mutect2, varscan2
- TAF1C | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs761364023, COSV58984932; called by muse, mutect2
- TAF1C | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1390845067, COSV58987575; called by muse, mutect2
- TBC1D9B | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs752701627, COSV100783672; called by muse, mutect2, varscan2
- TDRD1 | c.1763T>C p.M588T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52591224; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TENM2 | c.2041G>A p.G681R (on ENST00000518659 / NM_001122679.2; = p.G449R on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs910990669, COSV101319441; called by muse, mutect2, varscan2
- TESK1 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99427630; called by muse, mutect2, varscan2
- TET3 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV99996620; called by muse, mutect2, varscan2
- TEX10 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1349182870, COSV100887978; called by muse, mutect2, varscan2
- THRA | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV99225816; called by muse, mutect2, varscan2
- TLL1 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99289231; called by muse, mutect2, varscan2
- TMCC3 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs764045591, COSV54154738; called by muse, mutect2, varscan2
- TMCO4 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV99617663; called by muse, mutect2, varscan2
- TMEM132B | c.2551del p.Q851Sfs*39 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as COSV54763494; called by mutect2, pindel, varscan2
- TMEM132D | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101399677; called by muse, mutect2, varscan2
- TMEM168 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); catalogued as rs1214083496, COSV100454802, COSV57179032; called by muse, mutect2, varscan2
- TMEM30A | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100035004; called by muse, mutect2, varscan2
- TMEM53 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1288659340, COSV62407087; called by muse, mutect2, varscan2
- TMEM79 | c.487dup p.R163Pfs*9 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs780694092; called by mutect2, varscan2
- TMF1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs527848437, COSV101275472; called by muse, mutect2, varscan2
- TMPRSS11A | c.143del p.K48Rfs*11 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs763235501; called by mutect2, pindel, varscan2
- TMPRSS9 | c.1940T>C p.L647P (on ENST00000648592; = p.L613P on NM_182973.2) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211741; called by muse, mutect2, varscan2
- TNFRSF19 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.868); catalogued as rs1227458263, COSV50317326; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNNI3K | c.1919C>G p.T640S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.76); catalogued as COSV100438153; called by muse, mutect2, varscan2
- TOM1L2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs759002706, COSV100541251; called by muse, mutect2, varscan2
- TOP1MT | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1310928083, COSV61316348; called by muse, mutect2, varscan2
- TRAPPC12 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60849834; called by muse, mutect2, varscan2
- TRERF1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.097); catalogued as COSV61675374; called by muse, mutect2, varscan2
- TRIM14 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99271534; called by muse, mutect2, varscan2
- TRIM3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as COSV100624374; called by muse, mutect2, varscan2
- TRIM39 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as COSV100935928; called by muse, mutect2, varscan2
- TRIM67 | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.522); catalogued as COSV100792215; called by muse, mutect2, varscan2
- TRIM72 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100438503, COSV59067440; called by muse, mutect2, varscan2
- TRIM9 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53614844; called by muse, mutect2, varscan2
- TRIP12 | c.2015T>C p.V672A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99390982; called by muse, mutect2, varscan2
- TRMT2B | c.1057T>C p.C353R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100105696; called by muse, mutect2, varscan2
- TRPM2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs150593294, COSV55965307; called by muse, mutect2, varscan2
- TRPS1 | c.3827dup p.N1276Kfs*5 (on ENST00000220888 / NM_001330599.2; = p.N1289Kfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/136 reads (21%) | catalogued as rs1401148397; called by mutect2, varscan2
- TRPT1 | c.412C>A p.P138T (on ENST00000317459 / NM_001160393.1; = p.P89T on NM_031472.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV99656075; called by muse, mutect2, varscan2
- TTC13 | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100793042; called by muse, mutect2
- TTLL10 | c.1334G>A p.R445H (on ENST00000379289 / NM_001130045.2; = p.R372H on NM_153254.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs758599047, COSV64959360; called by muse, varscan2
- TTN | c.28798G>A p.A9600T (on ENST00000591111; = p.A8673T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | PolyPhen possibly damaging (0.725); catalogued as COSV60043386; called by muse, mutect2, varscan2
- TUBA3C | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV101313887; called by muse, mutect2, varscan2
- TUBG1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV99258943; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs760251146; called by mutect2, varscan2
- TXNRD2 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377714537; called by muse, mutect2, varscan2
- UBIAD1 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100954942; called by muse, mutect2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs763652408; called by mutect2, varscan2
- UBR5 | c.2418G>A p.Q806= | Splice Region (SNP) | VAF 25/144 reads (17%) | catalogued as COSV99642453; called by muse, varscan2
- UBR5 | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV55294910; called by muse, varscan2
- UMODL1 | c.3538G>A p.V1180M (on ENST00000408910 / NM_001004416.2; = p.V1308M on NM_173568.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs765010548, COSV101252727; called by muse, mutect2, varscan2
- UNC5CL | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99770991; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 36/58 reads (62%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCR11 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750552580, COSV73977240, COSV73977266; called by muse, mutect2, varscan2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs780272979; called by mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs749830910; called by mutect2, varscan2
- USP34 | c.8240A>G p.H2747R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1406525485, COSV101277238; called by muse, mutect2, varscan2
- USP48 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV100380271; called by muse, varscan2
- UTP14C | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as rs769412664, COSV101584304; called by muse, mutect2, varscan2
- VAV2 | c.1846G>A p.V616M (on ENST00000371850 / NM_001134398.2; = p.V606M on NM_003371.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as rs747112648, COSV100896229; called by muse, mutect2, varscan2
- VCAN | c.5240C>T p.S1747L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs376380721; ClinVar: benign; called by muse, mutect2, varscan2
- VCP | c.1847del p.N616Mfs*63 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs751290466; called by mutect2, varscan2
- VLDLR | c.2107A>G p.K703E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs370208560; called by muse, mutect2, varscan2
- VMA21 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100377876; called by muse, mutect2, varscan2
- VPS13B | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347218901, COSV100662116; called by muse, mutect2, varscan2
- VPS51 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV99659854; called by muse, mutect2, varscan2
- VWF | c.5971G>A p.G1991S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV99780259; called by muse, mutect2, varscan2
- WDR11 | c.1439del p.N480Tfs*32 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs747938475; called by mutect2, pindel, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 21/29 reads (72%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK3 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs782328561, COSV100672172; called by muse, mutect2, varscan2
- YAE1 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785095; called by muse, mutect2, varscan2
- ZBED4 | c.2509A>G p.S837G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1371379235, COSV99351757; called by muse, mutect2, varscan2
- ZBTB41 | c.494del p.L165Wfs*4 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs1247167282; called by mutect2, pindel, varscan2
- ZFAT | c.2243-3del | Splice Region (DEL) | VAF 6/52 reads (12%) | catalogued as rs35184160; called by mutect2, pindel
- ZFP91 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV100284761; called by muse, mutect2, varscan2
- ZIC1 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV51558184, COSV99291319; called by muse, mutect2, varscan2
- ZMYND8 | c.1561+2T>C p.X521_splice (on ENST00000311275 / NM_001363741.2; = p.X541_splice on NM_012408.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 42/133 reads (32%) | catalogued as COSV99521333; called by muse, mutect2, varscan2
- ZNF229 | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs767037153, COSV52163601; called by muse, mutect2, varscan2
- ZNF234 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368023865; called by muse, mutect2, varscan2
- ZNF25 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224792, COSV56922322; called by muse, mutect2, varscan2
- ZNF300 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.295); catalogued as rs566492867, COSV99200236; called by muse, mutect2, varscan2
- ZNF324 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs995043554, COSV99543257; called by muse, mutect2, varscan2
- ZNF418 | c.1177A>G p.T393A | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV68675475; called by muse, mutect2, varscan2
- ZNF48 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs764537359, COSV100198232; called by muse, mutect2, varscan2
- ZNF571 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.152); catalogued as COSV100144032; called by muse, mutect2, varscan2
- ZNF573 | c.1348del p.T450Pfs*74 (on ENST00000536220 / NM_001172692.1; = p.T392Pfs*74 on NM_152360.3) | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as rs751020931; called by mutect2, pindel, varscan2
- ZNF638 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs755919835, COSV100040066; called by muse, mutect2, varscan2
- ZNF664 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs138031514; called by muse, mutect2, varscan2
- ZNF71 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100046345, COSV60150178; called by muse, mutect2, varscan2
- ZNF761 | c.949A>G p.R317G | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100483495; called by muse, mutect2, varscan2
- ZNF835 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369264555; called by muse, mutect2, varscan2
- ABCG1 | c.1825del p.V609Sfs*8 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTS15 | c.1356del p.F452Lfs*107 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- ALCAM | c.958del p.S320Afs*2 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.2150del p.P717Lfs*79 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.197del p.P66Qfs*116 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- ARID1B | c.2647del p.L883Wfs*18 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | called by mutect2, pindel, varscan2
- ARSJ | c.1735_1736del p.K579Efs*32 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- ARSJ | c.807_810del p.S270Hfs*18 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by pindel, varscan2
- ASPM | c.5039del p.N1680Mfs*4 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- ATAD2B | c.2715del p.K905Nfs*6 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- BMP3 | c.1073del p.K358Rfs*20 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- BUB1B | c.897del p.M300Cfs*31 | Frame Shift Del (DEL) | VAF 31/128 reads (24%) | called by mutect2, varscan2
- C1orf56 | c.864del p.F289Sfs*48 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- CALHM5 | c.738del p.F246Lfs*75 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- CAND1 | c.692_694del p.T231del | In Frame Del (DEL) | VAF 22/76 reads (29%) | called by pindel, varscan2
- CD93 | c.1144del p.A382Pfs*206 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- CDC20B | c.1325del p.P442Qfs*10 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.4627del p.L1543Yfs*14 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- CFAP300 | c.313del p.Q105Sfs*26 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by mutect2, pindel, varscan2
- CHRNA3 | c.998del p.P333Rfs*10 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | called by mutect2, pindel, varscan2
- CLCN3 | c.2394del p.D799Ifs*17 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- COL25A1 | c.1883del p.G628Afs*40 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- COMTD1 | c.694_711del p.V232_E237del | In Frame Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel*, varscan2*
- CSPG4 | c.2158del p.V720Wfs*22 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DDX42 | c.586del p.I196Sfs*29 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- DDX60L | c.3502_3503del p.N1168Pfs*5 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | called by mutect2, pindel, varscan2
- DMD | c.7975del p.V2659Sfs*3 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- EDN1 | c.192_193del p.Y65Lfs*24 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- ERICH1 | c.487del p.R163Gfs*3 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, varscan2
- FBXO4 | c.377del p.K126Sfs*46 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- FCGBP | c.9092A>G p.N3031S | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FNBP4 | c.2846dup p.W950Vfs*7 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA6A | c.143dup p.K49Efs*4 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- GRM7 | c.1767del p.W590Gfs*3 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.502del p.D168Ifs*4 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- H3C2 | c.134dup p.T46Hfs*53 | Frame Shift Ins (INS) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- HCN1 | c.2030dup p.N677Kfs*90 | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- HPSE2 | c.1272del p.F424Lfs*28 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- HSPA4 | c.2396del p.N799Mfs*50 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- IFNGR2 | c.520dup p.C174Lfs*28 | Frame Shift Ins (INS) | VAF 78/249 reads (31%) | called by mutect2, varscan2
- IHO1 | c.1390del p.I464Sfs*63 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, varscan2
- KCNH1 | c.990del p.F330Lfs*24 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- KCNN1 | c.391dup p.V131Gfs*45 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- KIF21A | c.2305dup p.T769Nfs*20 (on ENST00000361418 / NM_001378440.1; = p.T756Nfs*20 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- KRT7 | c.808_810del p.E270del | In Frame Del (DEL) | VAF 14/72 reads (19%) | called by pindel, varscan2
- KRTAP27-1 | c.449del p.N150Ifs*62 | Frame Shift Del (DEL) | VAF 56/211 reads (27%) | called by mutect2, pindel, varscan2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- MAGEA11 | c.26del p.G9Vfs*25 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- MAN2A2 | c.847del p.R283Afs*28 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 54/251 reads (22%) | called by mutect2, pindel, varscan2
- MEST | c.113del p.P38Lfs*34 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- MID1IP1 | c.470_471del p.V157Afs*13 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by pindel, varscan2
- N4BP3 | c.741del p.Y248Tfs*50 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- NAP1L2 | c.211del p.E71Kfs*26 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- NETO2 | c.648del p.A217Lfs*5 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, varscan2
- NRDE2 | c.3063dup p.D1022* | Frame Shift Ins (INS) | VAF 35/101 reads (35%) | called by mutect2, pindel, varscan2
- NUTM2A | c.685dup p.L229Pfs*42 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- OMD | c.11del p.L4* | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- OSTM1 | c.352del p.L118Sfs*30 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- PCDHB3 | c.190del p.A64Pfs*23 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- PCED1B | c.157del p.E53Sfs*2 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- PCLO | c.3476del p.K1159Sfs*6 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- PHF23 | c.349_352del p.S117Vfs*14 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- PHLPP1 | c.3706dup p.T1236Nfs*38 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- PIGC | c.492dup p.D165* | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- PIWIL2 | c.1730del p.N577Ifs*10 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | called by mutect2, pindel, varscan2
- PLCE1 | c.1890del p.H630Qfs*28 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- POLR2B | c.632del p.K211Rfs*66 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- PRRC2A | c.6464del p.P2155Hfs*58 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- PRRC2C | c.6803del p.K2268Rfs*5 (on ENST00000367742; = p.K2266Rfs*5 on NM_015172.4) | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- PTPN12 | c.1838_1839del p.S613* | Frame Shift Del (DEL) | VAF 64/210 reads (30%) | called by pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- RUFY1 | c.2012_2014del p.F671del | In Frame Del (DEL) | VAF 9/62 reads (15%) | called by pindel, varscan2
- SAP130 | c.1725del p.I576Lfs*152 | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | called by mutect2, pindel, varscan2
- SCAF1 | c.3805G>A p.A1269T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- SELP | c.2424dup p.N810Efs*18 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- SH2B1 | c.1423del p.R475Afs*68 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- SH3BGRL2 | c.164del p.P55Rfs*41 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- SHANK2 | c.3345del p.P1116Hfs*58 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.663dup p.Y222Lfs*38 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- SNX27 | c.265del p.A89Rfs*16 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- SOX9 | c.1431dup p.T478Hfs*100 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- ST6GAL1 | c.51_54del p.L18Cfs*30 | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | called by pindel, varscan2
- STX1A | c.280_283del p.K94Afs*12 | Frame Shift Del (DEL) | VAF 58/272 reads (21%) | called by mutect2, pindel, varscan2
- SULT2A1 | c.398del p.F133Sfs*5 | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | called by mutect2, pindel, varscan2
- SUOX | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- SV2A | c.374del p.G125Afs*2 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- THAP2 | c.407dup p.R137Efs*4 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- TMEM132A | c.1153del p.M385Wfs*25 (on ENST00000453848 / NM_178031.3; = p.M386Wfs*25 on NM_017870.4) | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- TMEM200C | c.1698del p.V567Ffs*37 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- TNR | c.820G>T p.G274W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TP53INP2 | c.186dup p.A63Rfs*70 | Frame Shift Ins (INS) | VAF 4/19 reads (21%) | called by mutect2, pindel
- TRMT13 | c.1271dup p.K425Efs*8 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- UBL4A | c.278del p.P93Rfs*6 | Frame Shift Del (DEL) | VAF 45/179 reads (25%) | called by mutect2, pindel, varscan2
- UNC79 | c.4477_4478del p.K1493Afs*10 (on ENST00000393151 / NM_001346218.2; = p.K1316Afs*10 on NM_020818.5) | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- USP33 | c.1398del p.K466Nfs*25 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- VGLL2 | c.72del p.Y25Tfs*5 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- VIRMA | c.1562del p.L521* | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- WDR46 | c.1390del p.V464Wfs*39 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- ZFYVE27 | c.562dup p.A188Gfs*38 | Frame Shift Ins (INS) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- ADAM10 | c.1489C>T p.L497= | Silent (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- ADAMTS16 | c.873C>T p.N291= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs766865413, COSV99943139; called by muse, mutect2, varscan2
- ADAR | c.216G>A p.R72= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99426785; called by muse, mutect2, varscan2
- ADAT1 | c.144C>T p.C48= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs369749892; called by muse, mutect2, varscan2
- ADCY8 | c.543G>A p.S181= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99654515; called by muse, mutect2, varscan2
- ADGRE3 | c.939C>A p.G313= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs746299422, COSV99506748; called by muse, mutect2, varscan2
- AGFG2 | c.282T>C p.P94= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV99499571; called by muse, mutect2, varscan2
- ALAD | c.924C>T p.R308= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99475073; called by muse, mutect2, varscan2
- ANKRD11 | c.6381C>T p.P2127= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1471416250, COSV99970686; called by muse, mutect2, varscan2
- ANKS3 | c.843C>T p.G281= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs763735355, COSV58510706; called by muse, mutect2, varscan2
- AQP10 | c.627C>T p.C209= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs559006639, COSV61474765, COSV61475957; called by muse, mutect2, varscan2
- ARFGEF2 | c.1044G>A p.S348= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs769880911, COSV100904497; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP33 | c.1779G>A p.T593= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs781506570, COSV99140169; called by muse, mutect2, varscan2
- ARHGEF28 | c.4230G>C p.L1410= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV55248481, COSV99710196; called by muse, mutect2, varscan2
- ARID3C | c.1182T>C p.G394= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99427069; called by muse, mutect2, varscan2
- ARV1 | c.711C>T p.A237= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs752337224, COSV100048622; called by muse, mutect2, varscan2
- ATG10 | c.327T>A p.P109= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99967345; called by muse, mutect2, varscan2
- ATG2B | c.6081C>T p.A2027= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs751217088, COSV99952178; called by muse, mutect2, varscan2
- ATP9A | c.513C>T p.A171= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs566080700, COSV100125663; called by muse, mutect2, varscan2
193 further variants in this file (0 protein-altering or splice-affecting, 177 silent, 16 other) are not listed here.
